Somatic mutation profile of tumor specimen ALCH-B40S-TTP1-A (aliquot ALCH-B40S-TTP1-A-1-0-D-A80D-36) from ALCHEMIST case ALCH-B40S, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 60.5 years (22,101 days).
Specimen ALCH-B40S-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 942fba28-483b-4eb7-a734-cc6e0e89cb2b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B40S-NB1-A (Blood Derived Normal), aliquot ALCH-B40S-NB1-A-1-0-D-A80D-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5b331473-111d-4bc0-814e-3d08c577a95a

The open-access MAF lists 463 somatic variants for this specimen: 328 protein-altering or splice-affecting, 86 silent, 49 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 274, Silent 86, Nonsense Mutation 26, Intron 24, Splice Site 14, Frame Shift Del 9, RNA 9, 5'UTR 7, 3'UTR 6, Frame Shift Ins 3, 3'Flank 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.722C>A p.S241Y | Missense Mutation (SNP) | VAF 112/601 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934573, CM1212186, CM920673, COSV52661688, COSV52662386, COSV52713934, COSV52760886; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- TP53 | c.395A>G p.K132R | Missense Mutation (SNP) | VAF 72/458 reads (16%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1057519996, COSV52666637, COSV52701687, COSV52759171; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCA1 | c.1560C>G p.I520M | Missense Mutation (SNP) | VAF 53/779 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.065); catalogued as rs1240670240; called by muse, mutect2
- ACTR6 | c.1043C>T p.S348F | Missense Mutation (SNP) | VAF 42/191 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.454); catalogued as rs772915718; called by muse, mutect2, varscan2
- ADAM12 | c.501C>G p.F167L | Missense Mutation (SNP) | VAF 84/455 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs1365088875; called by muse, varscan2
- ADCY8 | c.1696G>A p.E566K | Missense Mutation (SNP) | VAF 49/185 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.745); catalogued as COSV53905477; called by muse, mutect2, varscan2
- ADGRG4 | c.6059C>G p.P2020R | Missense Mutation (SNP) | VAF 33/167 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV54956744, COSV99796699; called by muse, mutect2, varscan2
- ADGRG4 | c.6314C>T p.P2105L | Missense Mutation (SNP) | VAF 28/378 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV54964843; called by muse, mutect2
- ADGRL3 | c.2051G>T p.S684I (on ENST00000506720 / NM_001322402.2; = p.S616I on NM_015236.6) | Missense Mutation (SNP) | VAF 66/174 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as COSV63368652; called by muse, mutect2, varscan2
- AFF2 | c.3289G>C p.V1097L | Missense Mutation (SNP) | VAF 108/326 reads (33%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.8); catalogued as COSV99662610; called by muse, varscan2
- AQP6 | c.253G>T p.V85L | Missense Mutation (SNP) | VAF 115/381 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.105); catalogued as rs542164923; called by muse, mutect2, varscan2
- ARHGEF11 | c.410C>T p.S137F | Missense Mutation (SNP) | VAF 45/173 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.248); catalogued as rs767620495; called by muse, mutect2, varscan2
- ARMC5 | c.293C>G p.S98W | Missense Mutation (SNP) | VAF 64/234 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.468); catalogued as COSV99192919; called by muse, mutect2, varscan2
- ATP10A | c.4277T>C p.L1426P | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.018); catalogued as rs774207574; called by mutect2, varscan2
- C10orf71 | c.1805T>A p.F602Y | Missense Mutation (SNP) | VAF 32/190 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.095); catalogued as rs1024869493; called by muse, mutect2, varscan2
- C7 | c.2263T>C p.Y755H | Missense Mutation (SNP) | VAF 32/223 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs562422850; called by muse, mutect2, varscan2
- CALML4 | c.298G>A p.G100R | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs764702099; called by mutect2, varscan2
- CASC3 | c.1264G>C p.E422Q | Missense Mutation (SNP) | VAF 50/372 reads (13%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.477); catalogued as COSV99229954; called by muse, mutect2, varscan2
- CBWD5 | c.952G>T p.G318* (on ENST00000382405 / NM_001330668.1; = p.G270* on NM_001024916.3) | Nonsense Mutation (SNP) | VAF 104/1174 reads (9%) | catalogued as rs1166176867; called by muse, mutect2
- CD1E | c.115A>G p.M39V | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100937013; called by muse, mutect2, varscan2
- CDH12 | c.1657C>G p.R553G | Missense Mutation (SNP) | VAF 32/153 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.16); catalogued as rs1186005652, COSV101203414; called by mutect2, varscan2
- CDH7 | c.1960G>C p.D654H | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100542520; called by muse, mutect2, varscan2
- CFAP46 | c.6766G>C p.E2256Q | Missense Mutation (SNP) | VAF 19/186 reads (10%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.643); catalogued as COSV54150261; called by muse, mutect2
- CNTNAP2 | c.2047G>A p.E683K | Missense Mutation (SNP) | VAF 233/561 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.557); catalogued as rs372580822, COSV62249920; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL4A2 | c.3578G>A p.R1193H | Missense Mutation (SNP) | VAF 72/450 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs1222391002; called by muse, varscan2
- CYP26C1 | c.7C>T p.P3S | Missense Mutation (SNP) | VAF 31/258 reads (12%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as rs34954610; called by muse, mutect2, varscan2
- CYP4F2 | c.1310C>A p.P437H | Missense Mutation (SNP) | VAF 20/201 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV55620266; called by muse, mutect2
- DCAF12L2 | c.412G>C p.D138H | Missense Mutation (SNP) | VAF 40/246 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs181804861; called by muse, mutect2, varscan2
- DEFA4 | c.289G>T p.D97Y | Missense Mutation (SNP) | VAF 45/134 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); catalogued as COSV52404696; called by muse, mutect2, varscan2
- DNAI2 | c.1039C>A p.R347S | Missense Mutation (SNP) | VAF 112/453 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.802); catalogued as COSV56757634; called by muse, mutect2, varscan2
- DND1 | c.976G>C p.V326L | Missense Mutation (SNP) | VAF 81/281 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1268537067; called by muse, mutect2, varscan2
- DOCK11 | c.3472-1G>T p.X1158_splice | Splice Site (SNP) | VAF 43/229 reads (19%) | catalogued as COSV52237274; called by muse, mutect2, varscan2
- EPB41L4B | c.1634-1G>T p.X545_splice | Splice Site (SNP) | VAF 22/235 reads (9%) | catalogued as COSV101000942, COSV65802290; called by muse, mutect2
- ERCC6L2 | c.3517G>A p.D1173N | Missense Mutation (SNP) | VAF 91/315 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs1356310380; called by muse, mutect2, varscan2
- FAM47C | c.519C>A p.D173E | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.76); PolyPhen benign (0.059); catalogued as COSV100792325; called by muse, mutect2, varscan2
- FAM47C | c.2459G>T p.G820V | Missense Mutation (SNP) | VAF 49/335 reads (15%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.939); catalogued as COSV63723864; called by muse, mutect2, varscan2
- FAM78B | c.674G>T p.R225L | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.072); catalogued as COSV57979913, COSV99070153; called by muse, mutect2, varscan2
- FAM83A | c.1220C>A p.T407K | Missense Mutation (SNP) | VAF 60/215 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.068); catalogued as rs376998427; called by muse, mutect2, varscan2
- FASLG | c.179C>T p.P60L | Missense Mutation (SNP) | VAF 126/393 reads (32%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs780144691; called by muse, mutect2, varscan2
- FBXL16 | c.318C>G p.F106L | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.059); catalogued as COSV60964644; called by muse, mutect2
- FCRL4 | c.451G>T p.D151Y | Missense Mutation (SNP) | VAF 75/366 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.889); catalogued as COSV54862346; called by muse, mutect2, varscan2
- FRMPD3 | c.3934C>A p.Q1312K | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs765179604; called by muse, mutect2, varscan2
- GRIN3A | c.656C>A p.P219Q | Missense Mutation (SNP) | VAF 44/354 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100701806; called by muse, mutect2, varscan2
- HPSE2 | c.1406G>C p.R469P | Missense Mutation (SNP) | VAF 37/335 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.388); catalogued as rs553832137, COSV65186028; called by muse, mutect2, varscan2
- KALRN | c.2096A>G p.K699R | Missense Mutation (SNP) | VAF 40/490 reads (8%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.992); catalogued as COSV99563822; called by muse, mutect2
- KCNU1 | c.3157C>T p.Q1053* | Nonsense Mutation (SNP) | VAF 40/156 reads (26%) | catalogued as rs1040288419; called by muse, mutect2, varscan2
- KDM3A | c.1555A>G p.K519E | Missense Mutation (SNP) | VAF 105/344 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.201); catalogued as rs765810066; called by muse, mutect2, varscan2
- KLF15 | c.166G>T p.D56Y | Missense Mutation (SNP) | VAF 28/251 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.96); catalogued as rs147701754; called by muse, mutect2, varscan2
- KMT2D | c.4685A>G p.K1562R | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.219); catalogued as COSV99985476; called by muse, mutect2, varscan2
- LRP2 | c.11757C>A p.H3919Q | Missense Mutation (SNP) | VAF 289/911 reads (32%) | SIFT tolerated (0.68); PolyPhen benign (0.018); catalogued as COSV55566824; called by muse, mutect2, varscan2
- LRRTM1 | c.1061T>G p.L354R | Missense Mutation (SNP) | VAF 65/176 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775910242; called by muse, varscan2
- MAGI2 | c.344G>T p.R115L | Missense Mutation (SNP) | VAF 99/426 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as COSV62641607; called by muse, mutect2, varscan2
- MALSU1 | c.344C>T p.P115L | Missense Mutation (SNP) | VAF 34/273 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs146146722; called by muse, mutect2, varscan2
- MCM8 | c.449A>G p.E150G | Missense Mutation (SNP) | VAF 36/218 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.196); catalogued as rs992273876; called by muse, varscan2
- MICAL2 | c.2489G>A p.R830H | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.022); catalogued as rs368253911; called by muse, varscan2
- MTRR | c.1619G>T p.G540V (on ENST00000264668; = p.G513V on NM_002454.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 84/432 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs753414263; called by muse, mutect2, varscan2
- MYOF | c.5540G>T p.R1847L | Missense Mutation (SNP) | VAF 33/344 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1202083218, COSV63703709; called by muse, mutect2, varscan2
- NIPA2 | c.904G>A p.V302I | Missense Mutation (SNP) | VAF 150/547 reads (27%) | SIFT tolerated (0.5); PolyPhen benign (0.044); catalogued as rs767913997; called by muse, mutect2, varscan2
- NKAP | c.236G>T p.R79L | Missense Mutation (SNP) | VAF 39/266 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.071); catalogued as COSV101004279; called by muse, mutect2, varscan2
- NOA1 | c.2016G>C p.K672N | Missense Mutation (SNP) | VAF 51/638 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.153); catalogued as COSV51739092; called by muse, mutect2
- NTRK3 | c.1493C>A p.P498H | Missense Mutation (SNP) | VAF 67/279 reads (24%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.95); catalogued as COSV58125077; called by muse, mutect2, varscan2
- NYNRIN | c.4039C>T p.P1347S | Missense Mutation (SNP) | VAF 148/357 reads (41%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as rs371099138; called by muse, mutect2, varscan2
- OLFM4 | c.247T>G p.C83G | Missense Mutation (SNP) | VAF 102/342 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54580779; called by muse, mutect2, varscan2
- OR2M4 | c.673G>C p.V225L | Missense Mutation (SNP) | VAF 41/204 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV60707174; called by muse, mutect2, varscan2
- OR52N1 | c.556G>T p.V186L | Missense Mutation (SNP) | VAF 112/380 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.4); catalogued as rs749468499, COSV57692981; called by muse, mutect2, varscan2
- OR5D13 | c.274A>G p.R92G | Missense Mutation (SNP) | VAF 84/313 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.325); catalogued as COSV62332827; called by muse, mutect2, varscan2
- PCDH9 | c.802G>C p.G268R | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60570081, COSV60573033; called by muse, mutect2, varscan2
- PCDHA7 | c.71G>A p.W24* | Nonsense Mutation (SNP) | VAF 43/135 reads (32%) | catalogued as COSV65346234; called by muse, mutect2, varscan2
- PCLO | c.12376C>A p.H4126N | Missense Mutation (SNP) | VAF 23/148 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.116); catalogued as COSV61648664; called by muse, mutect2, varscan2
- PDZD2 | c.4333C>G p.Q1445E | Missense Mutation (SNP) | VAF 49/155 reads (32%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV99227064; called by muse, mutect2, varscan2
- PHTF1 | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 63/235 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766585356, COSV54732703; called by muse, mutect2, varscan2
- PLXNA4 | c.5546C>A p.A1849E | Missense Mutation (SNP) | VAF 82/392 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100325733; called by muse, mutect2, varscan2
- POLD2 | c.119G>A p.R40Q | Missense Mutation (SNP) | VAF 105/579 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.055); catalogued as rs1010143395, COSV56262971; called by muse, mutect2, varscan2
- POTEM | c.356C>G p.P119R | Missense Mutation (SNP) | VAF 168/510 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV69152208, COSV69155162; called by muse, varscan2
- PTPRD | c.4326G>C p.M1442I | Missense Mutation (SNP) | VAF 44/311 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100646186; called by muse, mutect2, varscan2
- PURG | c.763G>T p.D255Y | Missense Mutation (SNP) | VAF 65/181 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.26); catalogued as COSV99988158; called by muse, mutect2, varscan2
- RAB39B | c.88G>C p.E30Q | Missense Mutation (SNP) | VAF 112/301 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.042); catalogued as COSV65624392; called by muse, mutect2, varscan2
- RAD54L2 | c.2585A>G p.Y862C | Missense Mutation (SNP) | VAF 155/509 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1258601560; called by muse, mutect2, varscan2
- RBM20 | c.2132G>C p.R711P | Missense Mutation (SNP) | VAF 41/270 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99055436; called by muse, mutect2, varscan2
- RHBDD1 | c.229G>C p.D77H | Missense Mutation (SNP) | VAF 23/172 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs937859435, COSV58126481; called by muse, varscan2
- RHOXF2B | c.269G>A p.W90* | Nonsense Mutation (SNP) | VAF 154/1164 reads (13%) | catalogued as COSV101003962; called by muse, mutect2, varscan2
- RRP9 | c.583C>T p.P195S | Missense Mutation (SNP) | VAF 77/292 reads (26%) | SIFT tolerated (0.91); PolyPhen benign (0.005); catalogued as rs1485821404; called by muse, mutect2, varscan2
- RTKN2 | c.1405C>T p.P469S | Missense Mutation (SNP) | VAF 41/341 reads (12%) | SIFT tolerated (0.77); PolyPhen benign (0.001); catalogued as rs1260004388, COSV59522551; called by muse, mutect2, varscan2
- RTL1 | c.2722C>T p.R908C | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757578449; called by muse, varscan2
- SALL1 | c.2395C>A p.P799T | Missense Mutation (SNP) | VAF 121/390 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV51754853; called by muse, mutect2, varscan2
- SENP1 | c.507G>C p.L169F | Missense Mutation (SNP) | VAF 60/918 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as COSV50286694, COSV99136877; called by muse, mutect2
- SERPINC1 | c.571C>A p.Q191K | Missense Mutation (SNP) | VAF 75/647 reads (12%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.51); catalogued as CM034683, COSV62929065; called by muse, mutect2, varscan2
- SH3BP4 | c.2684C>T p.A895V | Missense Mutation (SNP) | VAF 23/203 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs986761903; called by muse, mutect2, varscan2
- SLC13A3 | c.518G>T p.S173I | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.079); catalogued as COSV51715184; called by muse, mutect2, varscan2
- SLC36A4 | c.1073G>T p.G358V | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1359411187, COSV100419239; called by muse, mutect2, varscan2
- SMC5 | c.761A>G p.Y254C | Missense Mutation (SNP) | VAF 141/570 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.99); catalogued as rs921161773; called by muse, mutect2, varscan2
- SYNE1 | c.7693G>C p.G2565R (on ENST00000367255 / NM_182961.4; = p.G2572R on NM_033071.3) | Missense Mutation (SNP) | VAF 40/89 reads (45%) | SIFT tolerated (0.66); PolyPhen benign (0.02); catalogued as COSV99582479; called by muse, mutect2, varscan2
- SYNE3 | c.2173G>T p.V725L | Missense Mutation (SNP) | VAF 122/371 reads (33%) | SIFT tolerated (0.75); PolyPhen benign (0.005); catalogued as rs572478808; called by muse, mutect2, varscan2
- TDRD5 | c.739G>T p.E247* | Nonsense Mutation (SNP) | VAF 52/282 reads (18%) | catalogued as COSV54249124; called by muse, mutect2, varscan2
- TIMELESS | c.1435C>T p.R479* | Nonsense Mutation (SNP) | VAF 4/42 reads (10%) | catalogued as rs145994145; called by mutect2, varscan2
- TLE6 | c.1594G>T p.A532S (on ENST00000246112 / NM_001143986.2; = p.A409S on NM_024760.3) | Missense Mutation (SNP) | VAF 99/263 reads (38%) | SIFT tolerated (0.44); PolyPhen benign (0.022); catalogued as COSV99504328; called by muse, mutect2, varscan2
- TMEM130 | c.1011C>G p.I337M | Missense Mutation (SNP) | VAF 42/338 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as rs781821415; called by muse, mutect2, varscan2
- TMEM145 | c.1280C>A p.P427H | Missense Mutation (SNP) | VAF 158/522 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.737); catalogued as COSV52089080; called by muse, mutect2, varscan2
- TTN | c.65562A>T p.K21854N (on ENST00000591111; = p.K14430N on NM_003319.4) | Missense Mutation (SNP) | VAF 21/181 reads (12%) | PolyPhen possibly damaging (0.693); catalogued as rs1482776876; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UPF1 | c.1925G>A p.R642H (on ENST00000599848 / NM_001297549.2; = p.R631H on NM_002911.4) | Missense Mutation (SNP) | VAF 27/331 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.034); catalogued as COSV53198026; called by muse, mutect2
- USH2A | c.7164C>A p.Y2388* | Nonsense Mutation (SNP) | VAF 61/405 reads (15%) | catalogued as COSV100236186; called by muse, mutect2, varscan2
- VAPA | c.418-1G>A p.X140_splice (on ENST00000400000 / NM_194434.3; = p.X185_splice on NM_003574.6) | Splice Site (SNP) | VAF 104/568 reads (18%) | catalogued as COSV61298093; called by muse, mutect2, varscan2
- WDR97 | c.1331C>T p.T444M | Missense Mutation (SNP) | VAF 59/244 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs1489657970; called by muse, mutect2, varscan2
- XPO6 | c.1229C>T p.T410I | Missense Mutation (SNP) | VAF 59/173 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.047); catalogued as rs1489154927; called by muse, mutect2, varscan2
- XRN2 | c.1781C>A p.P594Q | Missense Mutation (SNP) | VAF 25/136 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1208616874; called by muse, mutect2, varscan2
- ZDBF2 | c.1238C>G p.S413C | Missense Mutation (SNP) | VAF 32/208 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.753); catalogued as rs141439557, COSV65627901; called by muse, mutect2, varscan2
- ZFPM2 | c.3442G>T p.E1148* | Nonsense Mutation (SNP) | VAF 96/394 reads (24%) | catalogued as COSV65875197; called by muse, mutect2, varscan2
- ZNF808 | c.1398T>G p.C466W | Missense Mutation (SNP) | VAF 115/372 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV63121096; called by muse, mutect2, varscan2
- ZNF835 | c.1101C>A p.C367* | Nonsense Mutation (SNP) | VAF 64/186 reads (34%) | catalogued as rs1209536533; called by muse, mutect2, varscan2
- ACADSB | c.298C>A p.Q100K | Missense Mutation (SNP) | VAF 40/253 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- ACE | c.1403del p.G468Afs*57 | Frame Shift Del (DEL) | VAF 111/603 reads (18%) | called by mutect2, pindel, varscan2
- ADAMTS10 | c.1338-2A>T p.X446_splice | Splice Site (SNP) | VAF 26/413 reads (6%) | called by muse, mutect2
- ADD2 | c.850-1G>A p.X284_splice | Splice Site (SNP) | VAF 26/323 reads (8%) | called by muse, mutect2
- ADGRB1 | c.2000A>G p.Q667R | Missense Mutation (SNP) | VAF 19/196 reads (10%) | SIFT tolerated (1); PolyPhen possibly damaging (0.471); called by muse, mutect2
- ADGRG6 | c.3340C>T p.H1114Y | Missense Mutation (SNP) | VAF 105/322 reads (33%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- ADRA1D | c.845G>T p.R282L | Missense Mutation (SNP) | VAF 68/253 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- AKT1 | c.931G>T p.G311C | Missense Mutation (SNP) | VAF 70/212 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- ALDH9A1 | c.417G>C p.Q139H | Missense Mutation (SNP) | VAF 76/299 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); called by muse, mutect2, varscan2
- ALPK1 | c.1749G>A p.W583* | Nonsense Mutation (SNP) | VAF 76/430 reads (18%) | called by muse, mutect2, varscan2
- AMBP | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 16/268 reads (6%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.698); called by muse, mutect2
- AMER1 | c.3126G>T p.Q1042H | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.671); called by muse, mutect2, varscan2
- AMPH | c.1294C>A p.P432T | Missense Mutation (SNP) | VAF 76/240 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.026); called by muse, varscan2
- ANKRD30A | c.1058C>A p.S353* (on ENST00000611781; = p.S297* on NM_052997.2) | Nonsense Mutation (SNP) | VAF 44/207 reads (21%) | called by muse, mutect2, varscan2
- ANTXRL | c.1823C>A p.P608Q | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0.01); called by muse, varscan2
- APAF1 | c.766A>T p.S256C (on ENST00000551964 / NM_181861.2; = p.S245C on NM_001160.3) | Missense Mutation (SNP) | VAF 208/645 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.534); called by muse, mutect2, varscan2
- ARAP2 | c.4038+1G>T p.X1346_splice | Splice Site (SNP) | VAF 45/169 reads (27%) | called by muse, mutect2, varscan2
- ARHGAP11A | c.2213A>G p.K738R | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ARHGAP31 | c.1006+1del | Frame Shift Del (DEL) | VAF 86/422 reads (20%) | called by mutect2, pindel, varscan2
- ARHGAP40 | c.1285G>T p.A429S | Missense Mutation (SNP) | VAF 48/251 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- ASXL3 | c.605C>A p.S202Y | Missense Mutation (SNP) | VAF 93/231 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- ATP13A5 | c.143T>G p.L48R | Missense Mutation (SNP) | VAF 75/524 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- BOP1 | c.1980-1G>C p.X660_splice | Splice Site (SNP) | VAF 39/662 reads (6%) | called by muse, mutect2
- BRIP1 | c.1992C>A p.F664L | Missense Mutation (SNP) | VAF 91/483 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- BRSK1 | c.881C>A p.P294Q | Missense Mutation (SNP) | VAF 51/145 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- BST2 | c.297G>C p.M99I | Missense Mutation (SNP) | VAF 64/366 reads (17%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- BTBD7 | c.1066G>C p.A356P | Missense Mutation (SNP) | VAF 112/393 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BTG3 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 19/359 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.191); called by muse, mutect2
- C16orf95 | c.106G>T p.V36F | Missense Mutation (SNP) | VAF 61/248 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- C4orf54 | c.1186G>A p.D396N | Missense Mutation (SNP) | VAF 127/420 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- CACNA1F | c.5156+2T>A p.X1719_splice | Splice Site (SNP) | VAF 107/454 reads (24%) | called by muse, mutect2, varscan2
- CADM1 | c.562+2T>A p.X188_splice | Splice Site (SNP) | VAF 62/530 reads (12%) | called by muse, mutect2, varscan2
- CALR3 | c.831C>A p.H277Q | Missense Mutation (SNP) | VAF 178/603 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- CASS4 | c.1234T>C p.S412P | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2
- CCDC141 | c.298C>A p.Q100K | Missense Mutation (SNP) | VAF 61/570 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- CCDC3 | c.550C>G p.L184V | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.034); called by muse, mutect2
- CELA3A | c.700G>T p.G234C | Missense Mutation (SNP) | VAF 102/370 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- CEP112 | c.1204C>T p.Q402* | Nonsense Mutation (SNP) | VAF 11/89 reads (12%) | called by muse, varscan2
- CHUK | c.668A>T p.H223L | Missense Mutation (SNP) | VAF 139/827 reads (17%) | SIFT tolerated (0.88); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CLDN3 | c.382_383insT p.A128Vfs*183 | Frame Shift Ins (INS) | VAF 110/401 reads (27%) | called by mutect2, pindel, varscan2
- CLIC2 | c.35C>A p.P12H | Missense Mutation (SNP) | VAF 178/577 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.448); called by muse, mutect2, varscan2
- CNTNAP2 | c.894C>A p.H298Q | Missense Mutation (SNP) | VAF 95/240 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- CNTNAP5 | c.1402G>T p.D468Y | Missense Mutation (SNP) | VAF 125/464 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- COL1A2 | c.2896C>G p.H966D | Missense Mutation (SNP) | VAF 54/845 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2
- COL6A5 | c.4019T>C p.L1340P | Missense Mutation (SNP) | VAF 40/169 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- CRHR2 | c.952C>T p.L318F | Missense Mutation (SNP) | VAF 22/156 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CSMD2 | c.9413A>T p.Q3138L | Missense Mutation (SNP) | VAF 138/418 reads (33%) | SIFT tolerated (0.73); PolyPhen benign (0.003); called by muse, varscan2
- CTDNEP1 | c.289-1G>T p.X97_splice | Splice Site (SNP) | VAF 18/163 reads (11%) | called by muse, mutect2, varscan2
- CTTNBP2 | c.844C>A p.P282T | Missense Mutation (SNP) | VAF 36/204 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.529); called by muse, varscan2
- CUBN | c.5615A>G p.Y1872C | Missense Mutation (SNP) | VAF 75/434 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CUL7 | c.2788A>T p.S930C | Missense Mutation (SNP) | VAF 301/722 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- CXorf56 | c.292A>G p.T98A (on ENST00000536133 / NM_001170570.2; = p.T112A on NM_022101.4) | Missense Mutation (SNP) | VAF 71/443 reads (16%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- DACH2 | c.1655C>A p.T552N | Missense Mutation (SNP) | VAF 128/330 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- DCAF12L1 | c.512C>A p.P171H | Missense Mutation (SNP) | VAF 58/333 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- DCAF8L1 | c.1511A>T p.H504L | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- DCST2 | c.2246C>G p.P749R | Missense Mutation (SNP) | VAF 105/480 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- DENND1B | c.1733A>T p.H578L | Missense Mutation (SNP) | VAF 52/338 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.425); called by muse, mutect2, varscan2
- DENND2C | c.1666A>G p.S556G (on ENST00000393274 / NM_001256404.2; = p.S499G on NM_198459.4) | Missense Mutation (SNP) | VAF 88/357 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DGKI | c.2356del p.R786Vfs*4 | Frame Shift Del (DEL) | VAF 95/520 reads (18%) | called by mutect2, pindel, varscan2
- DLX6 | c.674T>A p.L225Q | Missense Mutation (SNP) | VAF 95/291 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- DOCK2 | c.2126C>A p.A709D | Missense Mutation (SNP) | VAF 115/350 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- DUOX2 | c.4053G>T p.K1351N | Missense Mutation (SNP) | VAF 16/173 reads (9%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2
- DUSP8 | c.1397G>T p.R466L | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.21); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- DUXA | c.47G>T p.R16M | Missense Mutation (SNP) | VAF 95/296 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- ENPP2 | c.2194A>T p.N732Y (on ENST00000075322 / NM_001040092.3; = p.N784Y on NM_006209.5) | Missense Mutation (SNP) | VAF 63/355 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- EOGT | c.842G>T p.G281V | Missense Mutation (SNP) | VAF 55/211 reads (26%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- ERBB2 | c.1054G>T p.E352* | Nonsense Mutation (SNP) | VAF 65/403 reads (16%) | called by muse, mutect2, varscan2
- ESCO2 | c.785A>T p.K262M | Missense Mutation (SNP) | VAF 38/77 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- ETV3L | c.458C>A p.A153E | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.315); called by muse, varscan2
- EXOC8 | c.382G>T p.G128W | Missense Mutation (SNP) | VAF 23/156 reads (15%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- EYS | c.5511del p.W1837Cfs*42 | Frame Shift Del (DEL) | VAF 54/239 reads (23%) | called by mutect2, pindel, varscan2
- FAM20C | c.158C>G p.A53G | Missense Mutation (SNP) | VAF 45/153 reads (29%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- FBN2 | c.337+1G>T p.X113_splice | Splice Site (SNP) | VAF 173/522 reads (33%) | called by muse, mutect2, varscan2
- FLG | c.7222T>A p.S2408T | Missense Mutation (SNP) | VAF 70/594 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.071); called by muse, varscan2
- FLNA | c.5608G>T p.A1870S (on ENST00000369850 / NM_001110556.2; = p.A1862S on NM_001456.3) | Missense Mutation (SNP) | VAF 215/718 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FOXI1 | c.56C>A p.P19H | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- FSTL4 | c.1610C>G p.S537C | Missense Mutation (SNP) | VAF 18/224 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.872); called by muse, mutect2
- GAB3 | c.95T>C p.V32A | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- GABRE | c.1291C>T p.P431S | Missense Mutation (SNP) | VAF 31/144 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- GHR | c.1379C>T p.P460L | Missense Mutation (SNP) | VAF 94/325 reads (29%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- GNAI2 | c.594G>T p.K198N | Missense Mutation (SNP) | VAF 51/259 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- GRIN3B | c.298G>T p.V100L | Missense Mutation (SNP) | VAF 108/298 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- GUCA1C | c.322A>T p.I108F | Missense Mutation (SNP) | VAF 78/384 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- HAVCR1 | c.232A>T p.K78* | Nonsense Mutation (SNP) | VAF 55/172 reads (32%) | called by muse, mutect2, varscan2
- HDAC7 | c.1093G>A p.A365T (on ENST00000427332; = p.A404T on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/156 reads (14%) | SIFT tolerated (0.7); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HECTD1 | c.2575C>A p.L859I | Missense Mutation (SNP) | VAF 88/323 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- HIP1 | c.365G>A p.S122N | Missense Mutation (SNP) | VAF 84/480 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- HK3 | c.2590G>T p.V864L | Missense Mutation (SNP) | VAF 38/120 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- HOXD13 | c.250G>A p.G84S | Missense Mutation (SNP) | VAF 148/307 reads (48%) | SIFT tolerated (0.29); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- HOXD13 | c.572C>G p.S191C | Missense Mutation (SNP) | VAF 40/634 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); called by muse, mutect2
- HPRT1 | c.25G>T p.V9L | Missense Mutation (SNP) | VAF 105/561 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- HSD17B6 | c.715G>T p.G239* | Nonsense Mutation (SNP) | VAF 14/254 reads (6%) | called by muse, mutect2
- IGKV1D-42 | c.69C>A p.D23E | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- ING1 | c.407G>T p.G136V | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- ITPRID1 | c.1358G>T p.R453I | Missense Mutation (SNP) | VAF 45/209 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- KIF7 | c.3977G>T p.R1326L | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- KLF3 | c.369G>A p.M123I | Missense Mutation (SNP) | VAF 131/485 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- KLHL20 | c.1627_1633del p.R543Vfs*15 | Frame Shift Del (DEL) | VAF 56/258 reads (22%) | called by mutect2, pindel, varscan2
- L1TD1 | c.2042C>A p.T681N | Missense Mutation (SNP) | VAF 41/136 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- LAS1L | c.716A>T p.D239V | Missense Mutation (SNP) | VAF 41/389 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.134); called by muse, mutect2
- LASP1 | c.411G>T p.E137D | Missense Mutation (SNP) | VAF 50/295 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LILRB5 | c.1496G>T p.G499V (on ENST00000449561 / NM_001081442.3; = p.G498V on NM_006840.5) | Missense Mutation (SNP) | VAF 71/204 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); called by muse, varscan2
- LINC02876 | n.202+2T>C | Splice Site (SNP) | VAF 49/209 reads (23%) | called by muse, mutect2, varscan2
- LOXL2 | c.2134G>C p.V712L | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- LRGUK | c.1868_1874del p.P623Rfs*53 | Frame Shift Del (DEL) | VAF 62/238 reads (26%) | called by pindel, varscan2
- LRP1B | c.6697C>G p.Q2233E | Missense Mutation (SNP) | VAF 9/172 reads (5%) | SIFT tolerated (0.37); PolyPhen benign (0.01); called by muse, mutect2
- LRRIQ1 | c.992A>C p.K331T | Missense Mutation (SNP) | VAF 125/373 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- LRRK2 | c.3232C>A p.P1078T | Missense Mutation (SNP) | VAF 155/574 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- MAGEA10 | c.666del p.K223Rfs*9 | Frame Shift Del (DEL) | VAF 48/235 reads (20%) | called by mutect2, pindel, varscan2
- MAGEA11 | c.20G>T p.R7I | Missense Mutation (SNP) | VAF 73/350 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- MAZ | c.1078C>T p.H360Y | Missense Mutation (SNP) | VAF 149/536 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MCM6 | c.1780A>T p.I594F | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.491); called by mutect2, varscan2
- MMAA | c.1163A>G p.Q388R | Missense Mutation (SNP) | VAF 56/304 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MMP9 | c.259G>T p.D87Y | Missense Mutation (SNP) | VAF 85/577 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MRC1 | c.2102G>T p.R701L | Missense Mutation (SNP) | VAF 89/647 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.453); called by muse, mutect2, varscan2
- MRC1 | c.2618+1G>T p.X873_splice | Splice Site (SNP) | VAF 80/405 reads (20%) | called by muse, mutect2, varscan2
- MROH5 | c.702G>T p.E234D | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- MRPL38 | c.628G>C p.E210Q | Missense Mutation (SNP) | VAF 57/369 reads (15%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.653); called by muse, mutect2, varscan2
- MSH4 | c.2243A>G p.H748R | Missense Mutation (SNP) | VAF 47/148 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- MYBPC1 | c.2612T>A p.L871* (on ENST00000550270 / NM_206820.2; = p.L878* on NM_002465.4) | Nonsense Mutation (SNP) | VAF 27/402 reads (7%) | called by muse, mutect2
- MYH4 | c.4445G>T p.S1482I | Missense Mutation (SNP) | VAF 46/309 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- NELL2 | c.1196A>T p.D399V | Missense Mutation (SNP) | VAF 98/285 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- NUF2 | c.1153G>A p.G385S | Missense Mutation (SNP) | VAF 62/256 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- OBSCN | c.6546G>C p.K2182N | Missense Mutation (SNP) | VAF 19/235 reads (8%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.973); called by muse, mutect2
- OCRL | c.384C>A p.D128E | Missense Mutation (SNP) | VAF 85/738 reads (12%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- OGDH | c.541G>C p.D181H | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.5); called by muse, mutect2
- OR10X1 | c.954G>T p.M318I | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.58); PolyPhen benign (0.001); called by mutect2, varscan2
- OR14J1 | c.253del p.M85Wfs*19 | Frame Shift Del (DEL) | VAF 208/637 reads (33%) | called by mutect2, pindel, varscan2
- OR1L6 | c.82C>A p.Q28K | Missense Mutation (SNP) | VAF 81/347 reads (23%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- OR2A2 | c.896C>G p.A299G | Missense Mutation (SNP) | VAF 56/142 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- OR4Q3 | c.600C>A p.D200E | Missense Mutation (SNP) | VAF 53/538 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.113); called by muse, mutect2
- OR6C3 | c.452T>G p.L151R | Missense Mutation (SNP) | VAF 95/297 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- OR8K3 | c.822del p.I275Yfs*10 | Frame Shift Del (DEL) | VAF 81/349 reads (23%) | called by mutect2, pindel, varscan2
- ORC5 | c.113A>G p.H38R | Missense Mutation (SNP) | VAF 28/225 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- PAGE4 | c.181G>A p.G61S | Missense Mutation (SNP) | VAF 56/241 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- PAK3 | c.959C>A p.P320H (on ENST00000262836 / NM_001324328.2; = p.P305H on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 51/442 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- PAPOLB | c.313A>G p.R105G | Missense Mutation (SNP) | VAF 49/236 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- PDZD7 | c.543G>T p.W181C | Missense Mutation (SNP) | VAF 42/185 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PHACTR1 | c.1547G>C p.R516T | Missense Mutation (SNP) | VAF 16/202 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); called by muse, mutect2
- PICK1 | c.331G>A p.G111S | Missense Mutation (SNP) | VAF 286/820 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- PIWIL1 | c.1660C>G p.Q554E | Missense Mutation (SNP) | VAF 66/262 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- PKDREJ | c.4864G>T p.V1622F | Missense Mutation (SNP) | VAF 108/360 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); called by muse, mutect2, varscan2
- PLCL1 | c.2104G>C p.D702H | Missense Mutation (SNP) | VAF 61/375 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- PLXNA4 | c.2615G>T p.G872V | Missense Mutation (SNP) | VAF 66/248 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PPP6R2 | c.892T>C p.Y298H | Missense Mutation (SNP) | VAF 74/210 reads (35%) | SIFT tolerated (0.49); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRG4 | c.2030C>A p.P677H | Missense Mutation (SNP) | VAF 50/448 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- PROM2 | c.2420G>T p.R807L | Missense Mutation (SNP) | VAF 60/186 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- PTPN22 | c.1906C>T p.P636S (on ENST00000359785 / NM_001193431.2; = p.P581S on NM_012411.5) | Missense Mutation (SNP) | VAF 11/255 reads (4%) | SIFT tolerated (0.85); PolyPhen benign (0.007); called by muse, mutect2
- PUM2 | c.3127G>A p.E1043K | Missense Mutation (SNP) | VAF 32/528 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2
- RAB7A | c.91A>T p.K31* | Nonsense Mutation (SNP) | VAF 142/609 reads (23%) | called by muse, mutect2, varscan2
- RAPGEF4 | c.1878G>T p.L626F | Missense Mutation (SNP) | VAF 61/511 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- RAPGEF4 | c.1879G>T p.E627* | Nonsense Mutation (SNP) | VAF 61/504 reads (12%) | called by muse, mutect2, varscan2
- RC3H1 | c.1243A>T p.K415* | Nonsense Mutation (SNP) | VAF 46/210 reads (22%) | called by muse, mutect2, varscan2
- RFX7 | c.3986A>C p.D1329A (on ENST00000559447 / NM_001368074.1; = p.D1426A on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/258 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- RNF144A | c.572A>T p.Y191F | Missense Mutation (SNP) | VAF 71/183 reads (39%) | SIFT tolerated (0.68); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- RP1 | c.6142G>A p.D2048N | Missense Mutation (SNP) | VAF 20/370 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- RPSA | c.700C>G p.P234A | Missense Mutation (SNP) | VAF 184/994 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- RTP2 | c.55G>T p.E19* | Nonsense Mutation (SNP) | VAF 41/180 reads (23%) | called by muse, mutect2, varscan2
- RYR2 | c.1873G>A p.V625I | Missense Mutation (SNP) | VAF 111/486 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- RYR2 | c.9995C>A p.T3332K | Missense Mutation (SNP) | VAF 79/484 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- RYR2 | c.10386G>T p.Q3462H | Missense Mutation (SNP) | VAF 28/326 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.135); called by muse, mutect2
- S100A14 | c.236T>G p.L79R | Missense Mutation (SNP) | VAF 30/328 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); called by muse, mutect2
- SCAF11 | c.1175G>T p.S392I | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- SCN11A | c.2317A>T p.M773L | Missense Mutation (SNP) | VAF 56/144 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SEMA3B | c.1101_1104dup p.Q369Ifs*75 | Frame Shift Ins (INS) | VAF 63/437 reads (14%) | called by mutect2, pindel, varscan2
- SEMA5A | c.1624C>T p.H542Y | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- SHOC1 | c.708T>A p.D236E | Missense Mutation (SNP) | VAF 62/298 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- SHOC2 | c.1279C>G p.L427V | Missense Mutation (SNP) | VAF 20/416 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); called by muse, mutect2
- SLC17A6 | c.364G>C p.E122Q | Missense Mutation (SNP) | VAF 73/278 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- SLC35F5 | c.499C>T p.P167S | Missense Mutation (SNP) | VAF 12/195 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); called by muse, mutect2
- SLC43A3 | c.503C>G p.S168C | Missense Mutation (SNP) | VAF 38/423 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SLC46A2 | c.838A>T p.K280* | Nonsense Mutation (SNP) | VAF 87/390 reads (22%) | called by muse, mutect2, varscan2
- SLC6A17 | c.1024T>A p.F342I | Missense Mutation (SNP) | VAF 63/212 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- SLC6A8 | c.1837G>A p.V613I | Missense Mutation (SNP) | VAF 128/376 reads (34%) | SIFT tolerated (0.49); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SLIT2 | c.514A>G p.R172G | Missense Mutation (SNP) | VAF 98/492 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, varscan2
- SLITRK1 | c.937G>C p.G313R | Missense Mutation (SNP) | VAF 62/264 reads (23%) | SIFT tolerated (0.59); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLITRK4 | c.1579G>T p.D527Y | Missense Mutation (SNP) | VAF 29/217 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SLITRK4 | c.305C>A p.A102D | Missense Mutation (SNP) | VAF 70/372 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SOX11 | c.1062C>A p.S354R | Missense Mutation (SNP) | VAF 84/316 reads (27%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.559); called by muse, mutect2, varscan2
- SP100 | c.2252A>T p.Q751L | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- SPATA19 | c.269T>G p.V90G | Missense Mutation (SNP) | VAF 76/228 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- SPRY2 | c.850G>T p.D284Y | Missense Mutation (SNP) | VAF 183/550 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- SPTBN1 | c.2061G>T p.M687I | Missense Mutation (SNP) | VAF 61/224 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- STON1 | c.254C>G p.T85S | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.541); called by muse, varscan2
- SVIL | c.3035G>T p.G1012V (on ENST00000355867 / NM_021738.3; = p.G586V on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/276 reads (19%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- SWT1 | c.1272G>T p.W424C | Missense Mutation (SNP) | VAF 20/278 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SYNM | c.1078A>T p.R360W | Missense Mutation (SNP) | VAF 127/431 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TANGO6 | c.2536G>T p.A846S | Missense Mutation (SNP) | VAF 86/358 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- TCERG1L | c.1015C>A p.P339T | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.257); called by muse, varscan2
- TIMD4 | c.336C>A p.C112* | Nonsense Mutation (SNP) | VAF 72/215 reads (33%) | called by muse, mutect2, varscan2
- TMEM108 | c.398C>A p.P133H | Missense Mutation (SNP) | VAF 32/236 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- TMEM115 | c.44_52del p.I15_A17del | In Frame Del (DEL) | VAF 30/162 reads (19%) | called by mutect2, pindel
- TMEM229A | c.301C>A p.H101N | Missense Mutation (SNP) | VAF 79/498 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.219); called by mutect2, varscan2
- TRIOBP | c.139G>T p.E47* | Nonsense Mutation (SNP) | VAF 34/648 reads (5%) | called by muse, mutect2
- TRPA1 | c.397G>T p.A133S | Missense Mutation (SNP) | VAF 178/418 reads (43%) | SIFT tolerated (0.56); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- TRPM1 | c.1543A>T p.R515W | Missense Mutation (SNP) | VAF 109/1018 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- TTN | c.5067G>T p.W1689C (on ENST00000591111; = p.W1643C on NM_003319.4) | Missense Mutation (SNP) | VAF 48/451 reads (11%) | PolyPhen probably damaging (0.999); called by muse, mutect2
- TTYH3 | c.469C>T p.Q157* | Nonsense Mutation (SNP) | VAF 81/365 reads (22%) | called by muse, mutect2, varscan2
- UHMK1 | c.881C>T p.P294L | Missense Mutation (SNP) | VAF 65/306 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- UNC13C | c.5251G>C p.E1751Q | Missense Mutation (SNP) | VAF 79/304 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- USH2A | c.6957G>C p.L2319= | Splice Region (SNP) | VAF 99/499 reads (20%) | called by muse, mutect2, varscan2
- VEGFC | c.873T>A p.C291* | Nonsense Mutation (SNP) | VAF 8/60 reads (13%) | called by muse, mutect2
- VPS13C | c.8767G>T p.V2923L (on ENST00000644861 / NM_020821.3; = p.V2880L on NM_017684.5) | Missense Mutation (SNP) | VAF 54/356 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.164); called by muse, varscan2
- VPS33B | c.1461C>G p.I487M | Missense Mutation (SNP) | VAF 55/913 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); called by muse, mutect2
- WDR59 | c.1485+1G>C p.X495_splice | Splice Site (SNP) | VAF 30/248 reads (12%) | called by muse, varscan2
- WDR72 | c.2127dup p.G710Wfs*2 | Frame Shift Ins (INS) | VAF 9/50 reads (18%) | called by mutect2, pindel, varscan2
- YWHAE | c.243G>C p.M81I | Missense Mutation (SNP) | VAF 44/524 reads (8%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.062); called by muse, mutect2
- ZFP36 | c.568A>G p.S190G (on ENST00000594442; = p.S184G on NM_003407.5) | Missense Mutation (SNP) | VAF 57/127 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZFP36 | c.569G>A p.S190N (on ENST00000594442; = p.S184N on NM_003407.5) | Missense Mutation (SNP) | VAF 56/123 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- ZHX2 | c.67G>T p.V23L | Missense Mutation (SNP) | VAF 141/483 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZKSCAN2 | c.1250C>G p.A417G | Missense Mutation (SNP) | VAF 131/428 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF248 | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 51/266 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF280A | c.1096T>C p.C366R | Missense Mutation (SNP) | VAF 140/371 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ZNF3 | c.587G>T p.G196V | Missense Mutation (SNP) | VAF 91/265 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- ZNF681 | c.1691G>T p.C564F | Missense Mutation (SNP) | VAF 85/611 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ZNF729 | c.3369G>T p.K1123N | Missense Mutation (SNP) | VAF 68/1022 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); called by muse, mutect2
- ZNF746 | c.568C>T p.Q190* | Nonsense Mutation (SNP) | VAF 67/204 reads (33%) | called by muse, mutect2, varscan2
- ZNF841 | c.2015C>T p.T672I (on ENST00000426391 / NM_001369830.1; = p.T788I on NM_001136499.1 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/150 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.45); called by muse, mutect2, varscan2
- ZNF98 | c.734A>G p.K245R | Missense Mutation (SNP) | VAF 34/822 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.305); called by muse, mutect2
- ACACB | c.3156C>T p.R1052= | Silent (SNP) | VAF 84/318 reads (26%) | called by muse, mutect2, varscan2
- ADGRG4 | c.1440A>G p.V480= | Silent (SNP) | VAF 28/146 reads (19%) | catalogued as rs1325271068; called by muse, mutect2, varscan2
- ADH1A | c.957T>A p.I319= | Silent (SNP) | VAF 58/398 reads (15%) | called by muse, mutect2, varscan2
- ADRA1A | c.228C>A p.T76= | Silent (SNP) | VAF 63/183 reads (34%) | called by muse, mutect2, varscan2
- AKAP12 | c.4632C>T p.T1544= | Silent (SNP) | VAF 70/213 reads (33%) | called by muse, mutect2, varscan2
- ARID5B | c.3021G>A p.G1007= | Silent (SNP) | VAF 13/66 reads (20%) | catalogued as rs748858778; called by muse, mutect2, varscan2
- ARNT2 | c.810G>C p.V270= | Silent (SNP) | VAF 64/298 reads (21%) | catalogued as rs1566991026; called by muse, mutect2, varscan2
- BRIX1 | c.756T>G p.T252= | Silent (SNP) | VAF 44/182 reads (24%) | called by muse, mutect2, varscan2
- CARD6 | c.2322A>T p.A774= | Silent (SNP) | VAF 80/301 reads (27%) | called by muse, mutect2, varscan2
- CHAT | c.972C>A p.L324= | Silent (SNP) | VAF 76/497 reads (15%) | called by muse, mutect2, varscan2
- CNGA3 | c.1728G>T p.L576= | Silent (SNP) | VAF 140/1016 reads (14%) | called by muse, mutect2, varscan2
- COL19A1 | c.2481T>C p.S827= | Silent (SNP) | VAF 36/134 reads (27%) | called by muse, mutect2, varscan2
- CSMD3 | c.10653C>A p.R3551= (on ENST00000297405 / NM_001363185.1; = p.R3382= on NM_052900.3) | Silent (SNP) | VAF 101/580 reads (17%) | catalogued as COSV99833973; called by muse, mutect2, varscan2
- DDC | c.720T>C p.V240= | Silent (SNP) | VAF 102/586 reads (17%) | called by muse, varscan2
- DENND1A | c.2715G>T p.T905= | Silent (SNP) | VAF 16/24 reads (67%) | called by muse, mutect2, varscan2
- DLGAP2 | c.2229G>T p.T743= | Silent (SNP) | VAF 105/343 reads (31%) | called by muse, mutect2, varscan2
- DNMT3B | c.2010G>T p.R670= | Silent (SNP) | VAF 188/801 reads (23%) | called by muse, varscan2
- DPEP3 | c.12G>T p.T4= | Silent (SNP) | VAF 67/225 reads (30%) | called by muse, mutect2, varscan2
- ENO2 | c.378G>A p.R126= | Silent (SNP) | VAF 70/178 reads (39%) | catalogued as COSV50396238; called by muse, mutect2, varscan2
- ESR1 | c.1785C>T p.V595= | Silent (SNP) | VAF 34/130 reads (26%) | called by muse, mutect2, varscan2
- FLG2 | c.3573T>C p.S1191= | Silent (SNP) | VAF 38/170 reads (22%) | catalogued as COSV66168738; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.702G>T p.L234= | Silent (SNP) | VAF 40/180 reads (22%) | catalogued as COSV100436226; called by muse, mutect2, varscan2
- FREM3 | c.472C>T p.L158= | Silent (SNP) | VAF 48/307 reads (16%) | called by muse, mutect2, varscan2
- FZD10 | c.1029C>T p.G343= | Silent (SNP) | VAF 47/188 reads (25%) | called by muse, mutect2, varscan2
- GATA6 | c.1173G>C p.V391= | Silent (SNP) | VAF 20/580 reads (3%) | called by muse, mutect2
- GLUD2 | c.789G>A p.G263= | Silent (SNP) | VAF 58/268 reads (22%) | called by muse, mutect2, varscan2
- GP1BB | c.207G>T p.A69= | Silent (SNP) | VAF 222/651 reads (34%) | called by muse, mutect2, varscan2
- H2AB1 | c.69C>A p.T23= | Silent (SNP) | VAF 17/150 reads (11%) | called by mutect2, varscan2
- HHLA1 | c.528C>A p.L176= | Silent (SNP) | VAF 224/841 reads (27%) | called by muse, mutect2, varscan2
- HLA-A | c.921C>T p.P307= | Silent (SNP) | VAF 98/229 reads (43%) | called by muse, mutect2, varscan2
- HNRNPUL1 | c.957C>T p.Y319= | Silent (SNP) | VAF 62/276 reads (22%) | called by muse, mutect2, varscan2
- INSYN2A | c.312C>A p.G104= | Silent (SNP) | VAF 24/242 reads (10%) | catalogued as COSV99727742; called by muse, mutect2
- KCNV2 | c.727C>A p.R243= | Silent (SNP) | VAF 329/684 reads (48%) | catalogued as rs143138491, CM1110036; called by muse, mutect2, varscan2
- KDM3A | c.3612C>T p.H1204= | Silent (SNP) | VAF 52/176 reads (30%) | catalogued as rs147714531; called by muse, mutect2, varscan2
- KLF4 | c.231C>T p.G77= | Silent (SNP) | VAF 131/523 reads (25%) | catalogued as rs750807475; called by muse, mutect2, varscan2
- LAIR2 | c.198C>T p.A66= | Silent (SNP) | VAF 131/365 reads (36%) | called by muse, mutect2, varscan2
- LPAR4 | c.357T>C p.L119= | Silent (SNP) | VAF 114/323 reads (35%) | catalogued as COSV101425085; called by muse, mutect2, varscan2
- LPIN3 | c.1851G>T p.V617= | Silent (SNP) | VAF 31/198 reads (16%) | called by muse, mutect2, varscan2
- MAGEA8 | c.625C>T p.L209= | Silent (SNP) | VAF 50/210 reads (24%) | called by muse, varscan2
- MARCHF6 | c.1623A>G p.E541= | Silent (SNP) | VAF 105/443 reads (24%) | called by muse, mutect2, varscan2
- MCF2L | c.1476G>A p.A492= (on ENST00000375608; = p.A460= on NM_024979.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 34/298 reads (11%) | catalogued as rs747754490; called by muse, mutect2, varscan2
- MINPP1 | c.573C>T p.S191= | Silent (SNP) | VAF 23/142 reads (16%) | catalogued as rs1228570702; called by muse, mutect2, varscan2
- MTHFSD | c.510C>T p.A170= (on ENST00000360900 / NM_001159377.2; = p.A169= on NM_022764.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 38/266 reads (14%) | catalogued as rs755394699; called by muse, varscan2
- MUC16 | c.29787G>C p.T9929= | Silent (SNP) | VAF 19/169 reads (11%) | catalogued as rs771496215; called by muse, mutect2, varscan2
- MYCBPAP | c.903C>A p.I301= | Silent (SNP) | VAF 14/150 reads (9%) | called by muse, mutect2
- NAV3 | c.2625G>C p.V875= | Silent (SNP) | VAF 40/618 reads (6%) | called by muse, mutect2
- NLRP14 | c.273G>A p.A91= | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as rs757165480, COSV55066287; called by muse, varscan2
- NLRP3 | c.1485G>T p.A495= | Silent (SNP) | VAF 48/264 reads (18%) | catalogued as rs373973057; called by muse, mutect2, varscan2
- NMRK2 | c.489C>T p.N163= | Silent (SNP) | VAF 35/120 reads (29%) | catalogued as rs202157781; called by muse, varscan2
- OLFML1 | c.282T>A p.R94= | Silent (SNP) | VAF 147/501 reads (29%) | called by muse, mutect2, varscan2
- OR10R2 | c.432T>A p.A144= | Silent (SNP) | VAF 41/381 reads (11%) | called by muse, mutect2, varscan2
- OR14C36 | c.267C>T p.T89= | Silent (SNP) | VAF 57/371 reads (15%) | catalogued as rs776873848, COSV58602530; called by muse, mutect2, varscan2
- OR1B1 | c.18T>C p.P6= | Silent (SNP) | VAF 15/61 reads (25%) | called by muse, mutect2, varscan2
- OR8D2 | c.621C>G p.T207= | Silent (SNP) | VAF 72/215 reads (33%) | called by muse, mutect2, varscan2
- OTOG | c.7494C>A p.P2498= | Silent (SNP) | VAF 52/115 reads (45%) | catalogued as rs1182291253; called by muse, mutect2, varscan2
- PAH | c.285C>A p.I95= | Silent (SNP) | VAF 34/364 reads (9%) | catalogued as COSV61020373; called by muse, mutect2
- PDE10A | c.1683G>T p.L561= | Silent (SNP) | VAF 54/352 reads (15%) | called by muse, varscan2
- POTEG | c.330G>A p.R110= | Silent (SNP) | VAF 128/2302 reads (6%) | catalogued as rs774258990; called by muse, mutect2
- PRKCD | c.252G>C p.V84= | Silent (SNP) | VAF 32/484 reads (7%) | called by muse, mutect2
- PRR23B | c.126A>T p.A42= | Silent (SNP) | VAF 15/134 reads (11%) | called by muse, mutect2, varscan2
- PRR36 | c.3837G>T p.G1279= | Silent (SNP) | VAF 33/100 reads (33%) | called by muse, mutect2, varscan2
- RYR3 | c.3570C>A p.I1190= | Silent (SNP) | VAF 20/216 reads (9%) | called by muse, mutect2, varscan2
- SALL1 | c.2394C>A p.V798= | Silent (SNP) | VAF 119/385 reads (31%) | called by muse, mutect2, varscan2
- SBNO2 | c.804C>T p.S268= | Silent (SNP) | VAF 26/509 reads (5%) | catalogued as rs527263008; called by muse, mutect2
- SCN1A | c.2685C>A p.L895= (on ENST00000303395 / NM_001202435.3; = p.L884= on NM_006920.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 50/421 reads (12%) | catalogued as COSV57661563; called by muse, mutect2, varscan2
- SEMA5A | c.2613A>T p.P871= | Silent (SNP) | VAF 65/334 reads (19%) | called by muse, mutect2, varscan2
- SEZ6L2 | c.378C>G p.P126= | Silent (SNP) | VAF 13/139 reads (9%) | called by muse, mutect2
- SLC7A14 | c.522G>T p.V174= | Silent (SNP) | VAF 130/263 reads (49%) | called by muse, mutect2, varscan2
- SPTA1 | c.81G>A p.R27= | Silent (SNP) | VAF 54/333 reads (16%) | called by muse, mutect2, varscan2
- SVIL | c.3447G>A p.R1149= (on ENST00000355867 / NM_021738.3; = p.R723= on NM_003174.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 40/324 reads (12%) | called by muse, varscan2
- TENM1 | c.5695C>A p.R1899= | Silent (SNP) | VAF 18/68 reads (26%) | catalogued as COSV64432948; called by muse, varscan2
- TNFRSF11B | c.180C>A p.T60= | Silent (SNP) | VAF 198/758 reads (26%) | catalogued as COSV52069734; called by muse, mutect2, varscan2
- TNFSF12 | c.535C>T p.L179= | Silent (SNP) | VAF 32/206 reads (16%) | called by muse, mutect2, varscan2
- TRBV6-1 | c.78C>T p.T26= | Silent (SNP) | VAF 46/204 reads (23%) | called by muse, mutect2, varscan2
- TRIM66 | c.2424G>A p.V808= | Silent (SNP) | VAF 100/330 reads (30%) | called by muse, mutect2, varscan2
- TRPC5 | c.366C>T p.S122= | Silent (SNP) | VAF 18/54 reads (33%) | catalogued as rs143012451, COSV53298726; called by muse, mutect2
- UBE2QL1 | c.315C>A p.A105= | Silent (SNP) | VAF 13/60 reads (22%) | called by muse, mutect2, varscan2
- UGT3A1 | c.642A>G p.Q214= | Silent (SNP) | VAF 106/641 reads (17%) | catalogued as rs1418018454; called by muse, mutect2, varscan2
- VIRMA | c.1881T>A p.L627= | Silent (SNP) | VAF 104/313 reads (33%) | called by muse, mutect2, varscan2
- VPS13A | c.3204G>A p.Q1068= | Silent (SNP) | VAF 18/204 reads (9%) | called by muse, mutect2
- WNK3 | c.2127G>T p.T709= | Silent (SNP) | VAF 127/321 reads (40%) | catalogued as COSV63614839; called by muse, mutect2, varscan2
- WWP1 | c.403T>C p.L135= | Silent (SNP) | VAF 13/184 reads (7%) | called by muse, mutect2
- ZBED9 | c.1920G>T p.R640= | Silent (SNP) | VAF 72/384 reads (19%) | called by muse, mutect2, varscan2
- ZC3H7B | c.1488C>T p.Y496= | Silent (SNP) | VAF 62/340 reads (18%) | catalogued as rs951145180, COSV60964856; called by muse, mutect2, varscan2
- ZNF479 | c.909C>A p.G303= | Silent (SNP) | VAF 62/530 reads (12%) | called by muse, mutect2, varscan2
- ZNF569 | c.1200T>C p.H400= | Silent (SNP) | VAF 49/414 reads (12%) | called by muse, mutect2, varscan2
- AC139769.1 | n.214-3736C>G | Intron (SNP) | VAF 114/244 reads (47%) | called by muse, mutect2, varscan2
- AHCYL2 | c.364-2041C>T | Intron (SNP) | VAF 36/788 reads (5%) | called by muse, mutect2
- AL450442.1 | n.802T>A | RNA (SNP) | VAF 80/271 reads (30%) | called by muse, varscan2
- ARMCX4 | c.1038+1524C>T | Intron (SNP) | VAF 21/243 reads (9%) | called by muse, mutect2
- ARNT | c.26-2812C>G | Intron (SNP) | VAF 14/315 reads (4%) | called by muse, mutect2
- ATP4A | c.-19A>T | 5'UTR (SNP) | VAF 27/184 reads (15%) | called by muse, mutect2, varscan2
- BCAR1 | c.12+3358A>C | Intron (SNP) | VAF 36/278 reads (13%) | called by muse, mutect2, varscan2
- C16orf82 | c.-72C>T | 5'UTR (SNP) | VAF 122/441 reads (28%) | catalogued as rs1240498628; called by muse, mutect2, varscan2
- C1QTNF6 | c.289+858T>C | Intron (SNP) | VAF 59/209 reads (28%) | called by muse, mutect2, varscan2
- CCDC150 | c.1866+723G>C | Intron (SNP) | VAF 36/209 reads (17%) | called by muse, mutect2, varscan2
- CCDC7 | c.1802-10491C>T | Intron (SNP) | VAF 69/418 reads (17%) | called by muse, mutect2, varscan2
- CCNL2 | c.1007-665G>A | Intron (SNP) | VAF 34/102 reads (33%) | called by muse, varscan2
- CHCHD7 | c.153+150C>G | Intron (SNP) | VAF 119/456 reads (26%) | called by muse, mutect2, varscan2
- CLU | c.*1161G>A | 3'UTR (SNP) | VAF 172/503 reads (34%) | called by muse, mutect2, varscan2
- DCAF17 | c.*338G>A | 3'UTR (SNP) | VAF 56/1178 reads (5%) | called by muse, mutect2
- DMD | c.-8C>T | 5'UTR (SNP) | VAF 72/406 reads (18%) | called by muse, mutect2, varscan2
- GNAI2 | c.*579_*580del | 3'UTR (DEL) | VAF 54/401 reads (13%) | called by mutect2, pindel, varscan2
- GRAMD1A | c.-64G>T | 5'UTR (SNP) | VAF 6/20 reads (30%) | called by muse, varscan2
- GRB14 | c.325-20500G>T | Intron (SNP) | VAF 74/293 reads (25%) | catalogued as rs1047775249; called by muse, mutect2, varscan2
- IGFN1 | c.1242-743G>T | Intron (SNP) | VAF 36/139 reads (26%) | called by muse, mutect2, varscan2
- MICOS13 | c.29+224_29+228del | Intron (DEL) | VAF 100/541 reads (18%) | called by mutect2, pindel, varscan2
- MMS19 | c.1219-10A>G | Intron (SNP) | VAF 37/251 reads (15%) | called by muse, mutect2, varscan2
- MTRNR2L6 | chr7:142671101 T>C | 3'Flank (SNP) | VAF 345/807 reads (43%) | catalogued as rs750535546; called by muse, mutect2, varscan2
- NBPF22P | n.296C>G | RNA (SNP) | VAF 131/494 reads (27%) | called by muse, mutect2, varscan2
- NBPF22P | n.988C>A | RNA (SNP) | VAF 119/410 reads (29%) | catalogued as rs530509607; called by muse, mutect2, varscan2
- NCR3 | c.497-167G>A | Intron (SNP) | VAF 18/190 reads (9%) | catalogued as rs773676183; called by muse, mutect2, varscan2
- NT5C3A | c.139-2771G>C | Intron (SNP) | VAF 111/554 reads (20%) | called by muse, mutect2, varscan2
- ODAPH | c.*27A>G | 3'UTR (SNP) | VAF 232/688 reads (34%) | called by mutect2, varscan2
- PDE10A | c.106+91567G>T | Intron (SNP) | VAF 24/154 reads (16%) | called by muse, mutect2, varscan2
- PPFIA2 | c.2643-12810C>T | Intron (SNP) | VAF 98/328 reads (30%) | catalogued as rs1282936634; called by muse, mutect2, varscan2
- PTPRT | c.2983-751T>C | Intron (SNP) | VAF 59/366 reads (16%) | catalogued as rs1460936815; called by muse, mutect2, varscan2
- RN7SL484P | chr15:99790315 A>T | 5'Flank (SNP) | VAF 8/170 reads (5%) | catalogued as rs1356638709; called by muse, mutect2
- RN7SL759P | chr15:20572629 A>T | 3'Flank (SNP) | VAF 158/1164 reads (14%) | called by muse, varscan2
- RPS6KB2 | c.-39C>T | 5'UTR (SNP) | VAF 59/206 reads (29%) | catalogued as rs1253929246; called by muse, mutect2, varscan2
- RUNX1T1 | c.1280-3837G>A | Intron (SNP) | VAF 65/146 reads (45%) | called by muse, mutect2, varscan2
- SGCE | c.770+31T>C | Intron (SNP) | VAF 65/235 reads (28%) | catalogued as rs1449825912; called by muse, mutect2, varscan2
- SH2D6 | n.680C>G | RNA (SNP) | VAF 20/240 reads (8%) | called by muse, mutect2
- SNORD109B | n.38G>T | RNA (SNP) | VAF 31/283 reads (11%) | called by muse, mutect2, varscan2
- SPATA31C2 | n.3106A>T | RNA (SNP) | VAF 179/685 reads (26%) | called by muse, mutect2, varscan2
- SPATA31C2 | n.1977C>T | RNA (SNP) | VAF 175/672 reads (26%) | catalogued as rs768108308; called by muse, mutect2, varscan2
- SQSTM1 | c.-8del | 5'UTR (DEL) | VAF 23/98 reads (23%) | called by mutect2, pindel, varscan2
- TCP10L3 | n.2674A>T | RNA (SNP) | VAF 62/694 reads (9%) | called by muse, mutect2
- TMEM175 | c.192+315G>T | Intron (SNP) | VAF 42/172 reads (24%) | called by muse, mutect2, varscan2
- U2AF2 | c.-42G>T | 5'UTR (SNP) | VAF 156/480 reads (33%) | catalogued as rs772717717; called by muse, mutect2, varscan2
- UBA6 | c.960+24G>C | Intron (SNP) | VAF 20/342 reads (6%) | called by muse, mutect2
- ZACN | c.544+331A>G | Intron (SNP) | VAF 22/81 reads (27%) | catalogued as rs762239562; called by muse, mutect2, varscan2
- ZNF81 | c.*2557C>A | 3'UTR (SNP) | VAF 35/222 reads (16%) | catalogued as rs1556891511; called by muse, mutect2, varscan2
- ZNF849P | n.1329A>G | RNA (SNP) | VAF 82/1037 reads (8%) | called by muse, mutect2
- ZNF99 | c.*3141G>T | 3'UTR (SNP) | VAF 26/198 reads (13%) | called by muse, varscan2
